Somatic mutation profile of tumor specimen TARGET-10-PASLBB-09A (aliquot TARGET-10-PASLBB-09A-01D) from TARGET case TARGET-10-PASLBB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.9 years (2,874 days).
Specimen TARGET-10-PASLBB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf08cc38-91e7-46b5-b2ff-82cc03f22db6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASLBB-10A (Blood Derived Normal), aliquot TARGET-10-PASLBB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc867581-b656-43d3-94ac-dd2365a5326f

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Intron 3, Splice Site 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNB1 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs869312821, CM164914, COSV66099716; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BCL11B | c.1415G>A p.R472H (on ENST00000357195 / NM_001282237.2; = p.R401H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1231938148, COSV61734054; called by muse, mutect2, varscan2
- CHST8 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs767515326, COSV52861404; called by muse, varscan2
- ECEL1 | c.1582-1G>T p.X528_splice | Splice Site (SNP) | VAF 8/119 reads (7%) | catalogued as rs1288821163; called by muse, mutect2
- EPPK1 | c.6508A>G p.K2170E | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as rs782037614, COSV73261875; called by muse, mutect2
- FAM110B | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1450130867, COSV64066756; called by muse, mutect2, varscan2
- HSPA5 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV61029724; called by muse, mutect2, varscan2
- MLANA | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs146459519; called by mutect2, varscan2
- NKX2-4 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.072); catalogued as COSV61085677; called by muse, mutect2, varscan2
- NOP53 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs769508522, COSV55881580; called by muse, mutect2, varscan2
- NUP210L | c.5380G>A p.G1794S | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV55153600; called by muse, mutect2, varscan2
- PPP3R2 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as rs775485051, COSV62456538; called by muse, varscan2
- PRUNE1 | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV54958583; called by muse, mutect2
- STOX2 | c.1402C>A p.H468N | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV100409045; called by muse, mutect2
- WT1 | c.1073_1074insC p.V359Cfs*14 | Frame Shift Ins (INS) | VAF 62/172 reads (36%) | catalogued as COSV60065649, COSV60065719, COSV60065736, COSV60066137, COSV60067652, COSV60068117, COSV60069984, COSV60070623, COSV60071183, COSV60072151, COSV60083061, COSV60084162, COSV99070056, COSV99070061, COSV99070065; called by mutect2, pindel*, varscan2
- AGXT2 | c.678A>C p.T226= | Splice Region (SNP) | VAF 119/257 reads (46%) | called by muse, mutect2, varscan2
- CD207 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRYBG3 | c.8881G>A p.E2961K | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); called by muse, mutect2
- TUBB | c.264C>A p.D88E | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); called by muse, mutect2
- WDR13 | c.1422C>A p.S474R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- CNKSR1 | c.1305G>A p.T435= (on ENST00000374253 / NM_001297647.2; = p.T428= on NM_006314.3) | Silent (SNP) | VAF 85/185 reads (46%) | catalogued as rs780434128, COSV64162949; called by muse, mutect2, varscan2
- MROH6 | c.696G>A p.S232= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs1407200231; called by muse, mutect2, varscan2
- PRSS12 | c.2340A>G p.T780= | Silent (SNP) | VAF 74/190 reads (39%) | called by muse, varscan2
- RASA4B | c.834C>T p.H278= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as rs1271771713; called by muse, mutect2, varscan2
- ADAMTS17 | c.2950-28C>T | Intron (SNP) | VAF 35/71 reads (49%) | catalogued as rs1206546385; called by muse, mutect2, varscan2
- SNRNP200 | c.4164+92G>T | Intron (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- TMEM273 | c.43+10024T>C | Intron (SNP) | VAF 46/95 reads (48%) | called by muse, mutect2, varscan2
